Gene-level copy-number profile of tumor specimen TCGA-XD-AAUI-01A from TCGA case TCGA-XD-AAUI, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 50.9 years (18,607 days).
Specimen TCGA-XD-AAUI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.d8a021c6-4cb0-43c7-b55f-3ca9d33ca54a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XD-AAUI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1713746a-43b5-4be0-90d8-88472de4a7cf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,166; copy number 2: 50,566; copy number 3: 1,093; copy number 4: 492; copy number 5: 199; copy number 6: 144; copy number 7: 16; copy number 8: 15; copy number 10: 9; copy number 11: 82; copy number 21: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XD-AAUI-01A-42D-A40V-01): tumor purity 0.19, ploidy 1.64, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 494 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:2,935,353–4,994,972, 5 genes, copy number 8 (within-gene range 2–8): CSMD1, AC026991.1, AC026991.2, RNA5SP251, AC027251.1.
- chr8:10,672,628–12,087,445, 59 genes, copy number 7–11: C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2, XKR6, MIR598, AF131215.3, AF131215.6, AF131215.5, AF131215.4, AF131215.2, AF131215.1, AF131215.7, LINC00529, RPL19P13, AF131216.2, AF131216.4, MTMR9, AF131216.1, SLC35G5, TDH, AF131216.3, FAM167A-AS1, RN7SL293P, RNU6-1084P, FAM167A, AF131216.5, BLK, AC022239.1, LINC00208, AC022239.2, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, AC107918.5, AC107918.6, DEFB136, DEFB135, DEFB134, AC107918.3, DEFB131E, AC107918.4, AC107918.2, AC107918.1, DEFB131C, DEFB130B, RNA5SP253.
- chr8:124,044,395–131,432,869, 109 genes, copy number 6–21 (within-gene range 3–21) (broad region; genes not listed).
- chr9:38,360,427–43,045,120, 139 genes, copy number 5 (broad region; genes not listed).
- chr11:131,187,022–131,350,917, 4 genes, copy number 6: AP002856.3, AP002856.1, AP002856.4, AP002856.2.
- chr11:131,385,249–131,385,363, 1 gene, copy number 6: RNU6ATAC12P.
- chr17:35,243,071–36,072,032, 60 genes, copy number 5 (within-gene range 1–5): SLFN5, AC022706.1, AC060766.2, SLFN11, AC060766.3, AC060766.6, AC060766.4, AC060766.7, AC060766.5, AC060766.1, SLFN12, SLFN13, AC015911.4, SLFN12L, AC015911.7, SLFN12L, AC015911.5, E2F3P1, TAF5LP1, AC015911.3, TOMM20P2, AC015911.9, AC015911.2, SLFN14, AC015911.6, AC015911.8, AC015911.1, SNHG30, SNORD7, PEX12, AP2B1, AC004134.1, TAF15, RASL10B, GAS2L2, MMP28, AC006237.1, C17orf50, AC015849.2, AC015849.3, AC015849.4, HEATR9, AC015849.6, AC015849.1, CCL5, 7SK, AC015849.5, LRRC37A9P, RDM1, LYZL6, AC244100.1, CCL16, CCL14, AC244100.2, CCL15-CCL14, CCL15, AC244100.3, AC244100.4, CCL23, CCL18.
- chr19:38,647,649–40,740,860, 117 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,166. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
